Somatic mutation profile of tumor specimen TARGET-10-PAPHNM-09A (aliquot TARGET-10-PAPHNM-09A-01D) from TARGET case TARGET-10-PAPHNM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (563 days).
Specimen TARGET-10-PAPHNM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68c2765e-10f1-4d2a-a417-c0392e7d3b08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHNM-10A (Blood Derived Normal), aliquot TARGET-10-PAPHNM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74b44589-2f73-421d-a9e6-96f5d928124a

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 2, Splice Site 1, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MORN1 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.108); catalogued as rs376656134; called by muse, mutect2, varscan2
- MYEOV | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1032034880; called by muse, mutect2, varscan2
- SPG21 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs756578242; called by muse, mutect2, varscan2
- BARX2 | c.574-1G>T p.X192_splice | Splice Site (SNP) | VAF 23/190 reads (12%) | called by muse, mutect2, varscan2
- IGLV4-69 | chr22:22031470 ins CATGCCCCGC | In Frame Ins (INS) | VAF 12/80 reads (15%) | called by mutect2, pindel
- NRXN3 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PRSS56 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.509); called by muse, mutect2
- BTBD8 | c.5101C>T p.L1701= (on ENST00000636805 / NM_001376131.1; = p.L1188= on NM_015237.4) | Silent (SNP) | VAF 19/134 reads (14%) | called by muse, mutect2, varscan2
- PATJ | c.4395T>C p.H1465= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs1046135269; called by muse, mutect2, varscan2
- NPAS2 | c.-23+708C>G | Intron (SNP) | VAF 51/124 reads (41%) | called by muse, mutect2, varscan2
- OXR1 | c.223+62054C>T | Intron (SNP) | VAF 76/193 reads (39%) | called by muse, mutect2, varscan2
- TRDJ1 | chr14:22449125 ins A | 5'Flank (INS) | VAF 8/19 reads (42%) | called by mutect2, varscan2*
